TARGET case TARGET-40-NAAHCU — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3b2463c8-d9cd-5802-82b7-685c76a84ce6

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 10 years; Vital status: Dead; Days to death: 2,482 days (6.8 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 10.2 years (3,715 days); Year of diagnosis: 2006; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 2,482 days (6.8 years); Sites of involvement: Lung, NOS.
   Pathology details: Necrosis percent: 99.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 739 days (2.0 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 739 days (2.0 years); Days to first event: 739 days (2.0 years); First event: Relapse.
- Days to follow up: 2,482 days (6.8 years); Year of follow up: 2013.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHCU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2482
- Protocol: BCM
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Site of initial relapse: Lung
